Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XA, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XA-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date:

Examination: Intraoperative examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Lesion resection – from the left breast with – outer quad. boundary

ICD-0-3

Carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9

pw 4/12/11

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: 20 minutes (from receipt of the material)

Clinical diagnosis: **Cancer of the left breast, Cancer of the left breast. Lesion on the boundary of outer quadrants. Marked typically. Please evaluate the margins.**

Examination performed on:

Results of immunohistochemical examination:

Part of the breast sized 9 x 7 x 4 cm with a skin flap of 5 x 1.5 cm. Margins: 1.3 cm to the base, 1.6 cm to the skin, 2.5 cm to the sternum, 2.5 cm to the axilla, 3 cm to the shoulder, 2 cm to the lower boundary

Result of intraoperative examination:

Carcinoma invasum

Compliance validated by:

Examination performed on:

Macroscopic description:

Part of the breast sized 9 x 7 x 4 cm with a skin flap of 5 x 1.5 cm. Margins: 1.3 cm to the base, 1.6 cm to the skin, 2.5 cm to the sternum, 2.5 cm to the axilla, 3 cm to the shoulder, 2 cm to the lower boundary.

Microscopic description:

Carcinoma ductale invasum - NHG2 (3+2+1/5 mitoses/10 HPF - visual area 0.55mm).

Additionally, benign lesions of the type adenosis sclerosans et "blunt duct" and lymph node free of neoplastic metastasis. Margins as in the macroscopic description.

Histopathological diagnosis:

Carcinoma ductale invasum mammae sinistrae. (NHG2, pT1c, pNO /sn/).

Invasive ductal carcinoma of the left breast. (NHG2, pT1c, pNO /sn/).

Compliance validated by:

Examination performed on:

	Yes	No

[page 2 of 2]
Examination: Intraoperative examination

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on:

Result of immunohistochemical test:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive carcinoma cells (Score = 1+ 1

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 2762308c-4148-42cc-96a3-8f4f22d1f607 (TCGA-D8-A1XA.9320030D-5E19-4BEE-99DA-366B6762DED1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).